Somatic mutation profile of tumor specimen TCGA-GC-A3RB-01A (aliquot TCGA-GC-A3RB-01A-12D-A21Z-08) from TCGA case TCGA-GC-A3RB, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 54.8 years (20,021 days).
Specimen TCGA-GC-A3RB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6cfb95a7-5278-4b65-9123-05b4e5d8a188.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-GC-A3RB-10A (Blood Derived Normal), aliquot TCGA-GC-A3RB-10A-01D-A21Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/359a5e23-e07d-49f9-af12-6f52adead587

The open-access MAF lists 186 somatic variants for this specimen: 129 protein-altering or splice-affecting, 54 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 54, Nonsense Mutation 4, Splice Site 4, Frame Shift Ins 3, Splice Region 3, Frame Shift Del 3, In Frame Del 1, 3'UTR 1, 3'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACHE | c.313G>T p.D105Y | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53820478; called by muse, mutect2, varscan2
- ACO1 | c.2658G>C p.K886N | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV59383348; called by muse, mutect2, varscan2
- AEN | c.293C>T p.A98V | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60430094; called by mutect2, varscan2
- ANKAR | c.642C>G p.I214M | Missense Mutation (SNP) | VAF 34/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55616520; called by muse, mutect2, varscan2
- ANKRD20A4P | c.655C>G p.L219V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.694); catalogued as COSV100628632; called by mutect2, varscan2
- APBA1 | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); catalogued as rs1370653772, COSV55234461; called by muse, mutect2, varscan2
- APOB | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.781); catalogued as rs1470195999, COSV51926777; called by muse, mutect2, varscan2
- AQR | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 51/175 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50045590; called by muse, mutect2, varscan2
- ATP1A1 | c.929C>G p.S310C | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.978); catalogued as COSV55193451; called by muse, mutect2, varscan2
- ATP6V1H | c.763C>G p.Q255E | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV62219737; called by muse, mutect2, varscan2
- AWAT2 | c.568T>A p.C190S | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT tolerated (0.91); PolyPhen benign (0.194); catalogued as COSV52144219; called by muse, mutect2
- BAP1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.027); catalogued as COSV56238890; called by muse, mutect2, varscan2
- BBS9 | c.1155G>A p.M385I | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.047); catalogued as COSV54166157; called by muse, mutect2
- BPTF | c.7828C>T p.H2610Y | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV58844049; called by muse, mutect2, varscan2
- C2CD4B | c.974C>T p.S325L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs753967216, COSV66791243; called by muse, mutect2, varscan2
- CADM2 | c.1254C>G p.I418M (on ENST00000407528 / NM_001167674.2; = p.I420M on NM_153184.4) | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs747188404, COSV67395186; called by muse, mutect2, varscan2
- CCDC151 | c.859G>C p.E287Q | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62697539; called by muse, mutect2, varscan2
- CDSN | c.593C>G p.S198C | Missense Mutation (SNP) | VAF 111/242 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV52539620; called by muse, mutect2
- CFHR2 | c.394C>T p.R132W | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs111586074, COSV66381906; called by muse, mutect2
- DHX38 | c.2024G>A p.R675H | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1284129655, COSV51700096; called by muse, mutect2, varscan2
- DHX57 | c.1577G>C p.R526P | Missense Mutation (SNP) | VAF 79/444 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.211); catalogued as COSV54882914, COSV54889599; called by muse, mutect2, varscan2
- DICER1 | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs746886465, CD112052, CM1514094, COSV58625793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DLG5 | c.5053C>T p.R1685C | Missense Mutation (SNP) | VAF 93/135 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1303519149, COSV64947929; called by muse, mutect2, varscan2
- DNAJB5 | c.645C>G p.I215M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV56624688; called by muse, mutect2, varscan2
- DOT1L | c.343T>A p.Y115N | Missense Mutation (SNP) | VAF 13/24 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67112411; called by muse, mutect2, varscan2
- EXOC8 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 53/133 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV50479278; called by muse, mutect2, varscan2
- EXPH5 | c.5132C>T p.S1711L | Missense Mutation (SNP) | VAF 39/141 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs920434753, COSV56206729; called by muse, mutect2, varscan2
- FASTKD3 | c.1873C>G p.Q625E | Missense Mutation (SNP) | VAF 59/141 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52948935; called by muse, mutect2, varscan2
- FCRL2 | c.821A>T p.Y274F | Missense Mutation (SNP) | VAF 16/221 reads (7%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.927); catalogued as COSV63834725; called by muse, mutect2
- FECH | c.1020C>A p.D340E | Missense Mutation (SNP) | VAF 32/232 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.993); catalogued as COSV50492198; called by muse, mutect2, varscan2
- FGG | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as rs1004506577, COSV60196396; called by muse, mutect2, varscan2
- FLG | c.6619G>C p.G2207R | Missense Mutation (SNP) | VAF 98/2900 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs531670104, COSV64246192; called by muse, mutect2
- FLG | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 73/496 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.728); catalogued as COSV64246196, COSV64251242; called by muse, mutect2, varscan2
- FMN2 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 23/113 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV60445945; called by muse, mutect2, varscan2
- FOXN2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV61319384; called by muse, mutect2, varscan2
- FPGS | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.848); catalogued as rs759152324, COSV64676115; called by muse, mutect2, varscan2
- FRZB | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV54555553; called by muse, mutect2, varscan2
- FUT9 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.733); catalogued as COSV56153668; called by muse, mutect2, varscan2
- GBP4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs771688858, COSV63253130; called by muse, mutect2, varscan2
- GLTP | c.54C>G p.I18M | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as COSV59172349; called by muse, mutect2, varscan2
- GPT | c.1398C>T p.F466= | Splice Region (SNP) | VAF 45/54 reads (83%) | catalogued as rs763542493, COSV52954369; called by muse, mutect2, varscan2
- GRM5 | c.1571G>A p.R524Q | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.673); catalogued as rs1215323612, COSV59621000; called by muse, mutect2, varscan2
- H3C11 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 65/151 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.898); catalogued as COSV100137683, COSV58899983; called by muse, mutect2, varscan2
- H6PD | c.1555C>T p.R519W | Missense Mutation (SNP) | VAF 24/288 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs35863691; called by muse, mutect2
- HPS3 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as COSV56056664; called by muse, mutect2, varscan2
- IFT43 | c.368+1G>A p.X123_splice (on ENST00000314067 / NM_001102564.3; = p.X128_splice on NM_052873.3) | Splice Site (SNP) | VAF 96/335 reads (29%) | catalogued as rs1566740262, COSV53140565; called by muse, mutect2, varscan2
- IGFN1 | c.2060G>A p.G687D (on ENST00000295591 / NM_001367841.1; = p.G3144D on NM_001164586.2) | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55181069; called by muse, mutect2, varscan2
- IRX1 | c.1190C>T p.P397L | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.203); catalogued as COSV57361651; called by muse, mutect2, varscan2
- ITPR1 | c.2121G>C p.E707D (on ENST00000354582; = p.E692D on NM_002222.7) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs762116038, COSV56997569; called by muse, mutect2
- KANSL1 | c.1652+1G>T p.X551_splice | Splice Site (SNP) | VAF 49/107 reads (46%) | catalogued as CS124331, COSV52267422, COSV52272538; called by muse, mutect2, varscan2
- KCNMA1 | c.3073G>C p.E1025Q (on ENST00000286628 / NM_001161352.2; = p.E967Q on NM_002247.4) | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54274258; called by muse, mutect2, varscan2
- KIF27 | c.3910C>T p.P1304S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99927217; called by muse, mutect2, varscan2
- KRT18 | c.220A>T p.M74L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV66316541; called by muse, mutect2, varscan2
- KRT35 | c.578G>C p.R193P | Missense Mutation (SNP) | VAF 92/183 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55844226; called by muse, mutect2, varscan2
- LHCGR | c.733A>G p.I245V | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.806); catalogued as rs936438880, COSV54301367; called by muse, mutect2, varscan2
- LYSMD3 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.08); catalogued as COSV60057972, COSV60058149; called by muse, mutect2, varscan2
- LYST | c.4678C>G p.L1560V | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV67711672; called by muse, mutect2, varscan2
- MED16 | c.637G>A p.V213M | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1204876691; called by muse, mutect2
- MKS1 | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 63/269 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); catalogued as COSV56598512, COSV99836713; called by muse, mutect2, varscan2
- NLRP4 | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV56720609; called by muse, mutect2, varscan2
- NOP58 | c.453G>T p.L151F | Missense Mutation (SNP) | VAF 47/195 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV51897173; called by muse, mutect2, varscan2
- NOXO1 | c.811G>C p.D271H (on ENST00000397280 / NM_172168.3; = p.D265H on NM_144603.4) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV50191770; called by muse, mutect2
- OLFM3 | c.739G>C p.A247P (on ENST00000338858 / NM_001288821.1; = p.A227P on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); catalogued as COSV58802108; called by muse, mutect2, varscan2
- OR2T4 | c.719T>C p.L240P | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV63544465, COSV63544829; called by muse, mutect2
- OSBPL1A | c.182G>T p.R61I | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as COSV60202028; called by muse, mutect2, varscan2
- PCLAF | c.204C>G p.F68L | Missense Mutation (SNP) | VAF 34/59 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55540060, COSV55541037; called by muse, mutect2, varscan2
- PCSK5 | c.4048G>A p.D1350N | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs780259704, COSV101377663; called by muse, mutect2
- PHF12 | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 26/168 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs770703592, COSV52020708, COSV52021407; called by muse, varscan2
- PIP5K1A | c.610C>G p.L204V (on ENST00000368888 / NM_001135638.2; = p.L191V on NM_003557.3) | Missense Mutation (SNP) | VAF 24/207 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV62959643; called by muse, mutect2, varscan2
- PLA2G2A | c.311G>A p.R104K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.49); PolyPhen benign (0.005); catalogued as COSV64287538; called by muse, mutect2
- PLAUR | c.209C>A p.S70* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV55391782; called by muse, mutect2, varscan2
- PLCG2 | c.690G>A p.L230= | Splice Region (SNP) | VAF 85/215 reads (40%) | catalogued as rs1219263211, COSV63874144; called by muse, mutect2, varscan2
- PLCZ1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.01); catalogued as rs528644759, COSV56857135; called by muse, mutect2, varscan2
- PMM1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 59/210 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV53448994; called by muse, varscan2
- PMM1 | c.100G>C p.E34Q | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV53449004; called by muse, varscan2
- POLR3B | c.2929G>A p.V977I | Missense Mutation (SNP) | VAF 48/172 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs199545845, COSV57281494; called by muse, mutect2, varscan2
- PRKAG1 | c.17C>G p.S6C | Missense Mutation (SNP) | VAF 42/68 reads (62%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.113); catalogued as COSV60294049; called by muse, mutect2, varscan2
- PURB | c.878G>T p.R293L | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.264); catalogued as COSV67480545; called by muse, mutect2, varscan2
- RAD17 | c.928-1G>A p.X310_splice (on ENST00000380774 / NM_133339.2; = p.X299_splice on NM_002873.1) | Splice Site (SNP) | VAF 4/42 reads (10%) | catalogued as COSV99281132; called by muse, mutect2
- RCE1 | c.209G>A p.R70Q | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV58993696; called by muse, mutect2, varscan2
- RGS14 | c.68A>T p.E23V | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as COSV68771797; called by muse, mutect2, varscan2
- RIMBP2 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1333476671, COSV55470482; called by muse, mutect2, varscan2
- RPS6KC1 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65301970; called by muse, mutect2, varscan2
- RSAD1 | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148371199, COSV51954634; called by muse, mutect2, varscan2
- SAFB2 | c.1560-1G>C p.X520_splice | Splice Site (SNP) | VAF 5/29 reads (17%) | catalogued as COSV53044504; called by muse, mutect2
- SATB2 | c.1643C>T p.P548L | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV53479431; called by muse, mutect2, varscan2
- SLC44A3 | c.1958G>C p.R653T (on ENST00000271227 / NM_001114106.3; = p.R605T on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as COSV54732955; called by muse, mutect2, varscan2
- SMPD2 | c.455G>C p.R152P | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57806589; called by muse, mutect2
- SMTNL2 | c.732G>C p.E244D (on ENST00000389313 / NM_001114974.2; = p.E100D on NM_198501.3) | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.168); catalogued as COSV58809433; called by muse, mutect2, varscan2
- SRP68 | c.1565C>T p.S522L | Missense Mutation (SNP) | VAF 84/179 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1314294204, COSV57164157; called by muse, mutect2, varscan2
- SRSF9 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.949); catalogued as COSV57570966; called by muse, mutect2, varscan2
- STARD5 | c.528C>A p.F176L | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.282); catalogued as COSV57154810, COSV57155850; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2962C>G p.H988D | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV59135682; called by muse, mutect2, varscan2
- TARS2 | c.118G>A p.E40K | Missense Mutation (SNP) | VAF 43/376 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV64696561; called by muse, mutect2, varscan2
- TARS2 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 37/329 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as COSV64696568; called by muse, mutect2, varscan2
- TBX2 | c.722A>G p.D241G | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53600591; called by muse, mutect2, varscan2
- TENT5A | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV60789082; called by muse, mutect2, varscan2
- TET1 | c.2417C>T p.S806F | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV65388096; called by muse, mutect2, varscan2
- TG | c.3459G>C p.K1153N | Missense Mutation (SNP) | VAF 79/243 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as rs1157601787, COSV55089573; called by muse, mutect2, varscan2
- TNRC18 | c.3518C>T p.P1173L | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.383); catalogued as rs751045614, COSV68169052; called by muse, mutect2, varscan2
- TRIM49 | c.57G>T p.M19I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.214); catalogued as COSV100316206; called by mutect2, varscan2
- TRPA1 | c.349C>T p.L117F | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51570100, COSV51570571; called by muse, mutect2, varscan2
- TRPS1 | c.1963G>C p.D655H (on ENST00000220888 / NM_001330599.2; = p.D668H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.236); catalogued as COSV55255858; called by muse, mutect2, varscan2
- TTN | c.87823G>T p.A29275S (on ENST00000591111; = p.A21851S on NM_003319.4) | Missense Mutation (SNP) | VAF 10/63 reads (16%) | PolyPhen possibly damaging (0.572); catalogued as COSV60258605; called by muse, mutect2, varscan2
- TXK | c.968A>T p.H323L | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51918470; called by muse, mutect2, varscan2
- UBAP2 | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT tolerated (0.26); PolyPhen benign (0.348); catalogued as rs1432595558, COSV62548359; called by muse, mutect2, varscan2
- UGGT1 | c.4491G>A p.M1497I | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.094); catalogued as COSV52139998; called by muse, mutect2, varscan2
- UGT1A3 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 40/338 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59395650; called by muse, mutect2, varscan2
- VIRMA | c.3034C>T p.L1012F | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV52589489, COSV99888926; called by muse, mutect2
- WDR44 | c.2604C>G p.N868K | Missense Mutation (SNP) | VAF 46/104 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0.019); catalogued as COSV54167069; called by muse, mutect2, varscan2
- WDR47 | c.1441C>G p.Q481E (on ENST00000369962 / NM_001142551.2; = p.Q482E on NM_014969.5) | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV63058739; called by muse, mutect2, varscan2
- WDR83OS | c.159G>A p.L53= | Splice Region (SNP) | VAF 19/61 reads (31%) | catalogued as COSV54419219; called by muse, varscan2
- XPR1 | c.599C>T p.A200V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.012); catalogued as COSV62559468; called by muse, mutect2, varscan2
- ZFP91 | c.763G>C p.E255Q | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.1); PolyPhen benign (0.255); catalogued as rs1218623961; called by muse, varscan2
- ZNF19 | c.1277C>A p.S426Y | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); catalogued as COSV55508617; called by muse, mutect2, varscan2
- ZNF776 | c.1474G>C p.E492Q | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV57816231; called by muse, mutect2, varscan2
- ACACA | c.5584A>G p.I1862V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CASP8AP2 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 30/32 reads (94%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EP300 | c.4942del p.Q1648Sfs*61 | Frame Shift Del (DEL) | VAF 20/90 reads (22%) | called by mutect2, pindel, varscan2
- FERMT1 | c.614_617dup p.F206Lfs*4 | Frame Shift Ins (INS) | VAF 56/175 reads (32%) | called by mutect2, pindel, varscan2
- FOXQ1 | c.436_438del p.N146del | In Frame Del (DEL) | VAF 20/91 reads (22%) | called by mutect2, pindel, varscan2
- IL27RA | c.514C>T p.Q172* | Nonsense Mutation (SNP) | VAF 44/339 reads (13%) | called by muse, mutect2, varscan2
- KMT2D | c.2396del p.P799Lfs*131 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- LRP4 | c.1437_1444del p.E480Lfs*41 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- MTMR8 | c.1538T>A p.M513K | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.028); called by muse, mutect2
- NR2C2 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 28/174 reads (16%) | called by muse, mutect2, varscan2
- PROX2 | c.31C>T p.Q11* | Nonsense Mutation (SNP) | VAF 27/114 reads (24%) | called by muse, mutect2, varscan2
- SLC25A4 | c.697dup p.T233Nfs*5 | Frame Shift Ins (INS) | VAF 27/46 reads (59%) | called by mutect2, pindel, varscan2
- TP53 | c.273dup p.P92Afs*57 | Frame Shift Ins (INS) | VAF 80/116 reads (69%) | called by mutect2, pindel, varscan2
- ACHE | c.1275G>A p.L425= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV53820458; called by muse, mutect2, varscan2
- ACSM4 | c.354C>T p.A118= | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as rs777659541, COSV68068200, COSV68069133; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2970G>A p.T990= | Silent (SNP) | VAF 36/684 reads (5%) | catalogued as rs368789447, COSV55005111; called by muse, mutect2
- ANK2 | c.10866G>A p.E3622= | Silent (SNP) | VAF 21/170 reads (12%) | catalogued as COSV52180347; called by muse, mutect2, varscan2
- ATP1A1 | c.759C>T p.T253= | Silent (SNP) | VAF 54/283 reads (19%) | catalogued as rs776666372, COSV55193443; called by muse, mutect2, varscan2
- CACNA1C | c.3972C>T p.S1324= | Silent (SNP) | VAF 33/200 reads (17%) | catalogued as COSV59756551; called by muse, mutect2, varscan2
- CCDC110 | c.1593A>G p.Q531= | Silent (SNP) | VAF 24/33 reads (73%) | catalogued as rs1339967709, COSV56872864; called by muse, mutect2, varscan2
- CEP250 | c.1624C>T p.L542= | Silent (SNP) | VAF 85/304 reads (28%) | catalogued as COSV61172932; called by muse, mutect2, varscan2
- CFAP65 | c.2988A>G p.E996= | Silent (SNP) | VAF 133/157 reads (85%) | catalogued as COSV58565153; called by muse, mutect2, varscan2
- CLTB | c.507C>T p.I169= | Silent (SNP) | VAF 21/60 reads (35%) | catalogued as COSV60045325; called by muse, mutect2, varscan2
- CPD | c.3033C>T p.L1011= | Silent (SNP) | VAF 148/255 reads (58%) | catalogued as COSV56715292; called by muse, mutect2, varscan2
- DST | c.4977C>T p.I1659= | Silent (SNP) | VAF 85/1260 reads (7%) | catalogued as rs373836234; called by muse, mutect2
- EID3 | c.39C>T p.S13= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100723599; called by muse, mutect2
- ELMOD3 | c.612G>A p.A204= | Silent (SNP) | VAF 15/89 reads (17%) | catalogued as rs202233755, COSV59774499; called by muse, mutect2, varscan2
- FAM120AOS | c.372G>C p.T124= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV52908973, COSV99466224; called by muse, mutect2, varscan2
- FLG | c.237C>T p.F79= | Silent (SNP) | VAF 50/246 reads (20%) | catalogued as COSV64246201; called by muse, mutect2
- FZD1 | c.1941C>T p.V647= | Silent (SNP) | VAF 37/143 reads (26%) | catalogued as COSV55312916; called by muse, mutect2, varscan2
- GATA1 | c.303G>A p.T101= | Silent (SNP) | VAF 41/45 reads (91%) | catalogued as rs145355350, COSV64963125; called by muse, mutect2, varscan2
- GGT1 | c.1098C>A p.I366= | Silent (SNP) | VAF 47/157 reads (30%) | catalogued as COSV50643702; called by muse, mutect2, varscan2
- GIT2 | c.1050C>G p.L350= (on ENST00000355312 / NM_057169.5; = p.L352= on NM_014776.5) | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as COSV58084039; called by muse, mutect2, varscan2
- GPER1 | c.402G>A p.S134= | Silent (SNP) | VAF 37/172 reads (22%) | catalogued as rs747021854, COSV52470230; called by muse, mutect2, varscan2
- GTPBP4 | c.348G>C p.L116= | Silent (SNP) | VAF 3/16 reads (19%) | catalogued as COSV62550303; called by muse, mutect2
- HECTD4 | c.2982G>C p.L994= | Silent (SNP) | VAF 56/1072 reads (5%) | catalogued as COSV61180979; called by muse, mutect2
- HSD17B14 | c.363G>A p.L121= | Silent (SNP) | VAF 41/157 reads (26%) | catalogued as rs993661924, COSV54414799; called by muse, mutect2, varscan2
- IGHE | c.342G>A p.V114= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- KCND3 | c.303G>A p.G101= | Silent (SNP) | VAF 34/186 reads (18%) | catalogued as COSV56186898; called by muse, mutect2, varscan2
- KIF2C | c.1422C>T p.F474= | Silent (SNP) | VAF 37/68 reads (54%) | catalogued as COSV64765420; called by muse, mutect2, varscan2
- KIFC2 | c.1644C>G p.A548= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as COSV56761221; called by mutect2, varscan2
- LGALS9 | c.309C>T p.F103= | Silent (SNP) | VAF 32/97 reads (33%) | catalogued as COSV56350482; called by muse, mutect2, varscan2
- MARCHF4 | c.1143C>A p.I381= | Silent (SNP) | VAF 38/88 reads (43%) | catalogued as COSV56107308, COSV99814244; called by muse, mutect2, varscan2
- MC5R | c.603G>A p.L201= | Silent (SNP) | VAF 258/976 reads (26%) | catalogued as COSV61254079, COSV61255399; called by muse, mutect2, varscan2
- MCM6 | c.2079G>A p.V693= | Silent (SNP) | VAF 180/352 reads (51%) | catalogued as COSV51468566; called by muse, mutect2, varscan2
- MINDY4 | c.1554G>C p.S518= | Silent (SNP) | VAF 23/160 reads (14%) | catalogued as COSV54675808, COSV54677294; called by muse, mutect2, varscan2
- MROH1 | c.2244G>A p.A748= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- NAV2 | c.78C>T p.H26= | Silent (SNP) | VAF 25/44 reads (57%) | catalogued as rs778481215, COSV62319478; called by muse, mutect2, varscan2
- OR4K2 | c.765C>T p.I255= | Silent (SNP) | VAF 24/120 reads (20%) | catalogued as COSV53851000; called by muse, mutect2, varscan2
- OR52E8 | c.873C>A p.A291= | Silent (SNP) | VAF 97/273 reads (36%) | catalogued as COSV66210636, COSV66213631; called by muse, mutect2, varscan2
- PABPC1 | c.1362C>T p.I454= | Silent (SNP) | VAF 21/152 reads (14%) | catalogued as COSV59405834; called by muse, mutect2, varscan2
- PHF12 | c.2250C>T p.I750= | Silent (SNP) | VAF 113/120 reads (94%) | catalogued as COSV52021393; called by muse, mutect2, varscan2
- PPEF2 | c.1179C>T p.S393= | Silent (SNP) | VAF 16/39 reads (41%) | catalogued as rs371148899; called by muse, mutect2, varscan2
- RIPK4 | c.1725C>T p.N575= (on ENST00000352483; = p.N527= on NM_020639.3) | Silent (SNP) | VAF 12/69 reads (17%) | catalogued as rs143300354; called by muse, mutect2, varscan2
- SCN9A | c.5046G>A p.E1682= (on ENST00000303354; = p.E1671= on NM_002977.3) | Silent (SNP) | VAF 64/188 reads (34%) | catalogued as COSV57620007; called by muse, mutect2, varscan2
- SLC25A42 | c.246C>T p.L82= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs200500398, COSV59381325; called by muse, mutect2, varscan2
- SLC25A42 | c.465C>T p.V155= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as COSV59381336; called by muse, mutect2, varscan2
- SLC47A1 | c.315G>C p.G105= | Silent (SNP) | VAF 24/70 reads (34%) | catalogued as COSV54503349; called by muse, mutect2, varscan2
- SLC6A6 | c.804G>C p.P268= | Silent (SNP) | VAF 37/86 reads (43%) | catalogued as COSV100692148, COSV62649911, COSV62651922; called by muse, mutect2, varscan2
- STRADA | c.525C>T p.I175= (on ENST00000336174 / NM_001363786.1; = p.I138= on NM_153335.6) | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV55564015; called by muse, mutect2, varscan2
- TANC1 | c.3489C>T p.F1163= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as rs779791920, COSV55094133; called by muse, mutect2, varscan2
- TUT4 | c.2115G>A p.R705= | Silent (SNP) | VAF 20/75 reads (27%) | catalogued as rs1218238743, COSV57118319; called by muse, mutect2, varscan2
- TXK | c.588G>C p.T196= | Silent (SNP) | VAF 8/39 reads (21%) | catalogued as COSV51918092, COSV99972528; called by muse, mutect2, varscan2
- UBAP2 | c.1692C>T p.I564= | Silent (SNP) | VAF 30/98 reads (31%) | catalogued as COSV62548354; called by muse, mutect2, varscan2
- VAV2 | c.2394C>T p.L798= | Silent (SNP) | VAF 6/35 reads (17%) | catalogued as rs375135670, COSV64084420; called by muse, mutect2
- VPS33A | c.1173T>C p.N391= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as COSV57358479; called by muse, mutect2, varscan2
- WNT6 | c.537G>A p.G179= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as COSV52110828; called by muse, mutect2, varscan2
- C8orf37 | c.*1G>A | 3'UTR (SNP) | VAF 12/152 reads (8%) | catalogued as COSV99713203; called by muse, mutect2
- NXF5 | n.1002A>G | RNA (SNP) | VAF 21/124 reads (17%) | catalogued as COSV53792820; called by muse, mutect2, varscan2
- RN7SL176P | chr12:100157655 C>A | 3'Flank (SNP) | VAF 28/82 reads (34%) | called by muse, mutect2, varscan2
